Somatic mutation profile of tumor specimen ALCH-AEJ4-TTP1-A (aliquot ALCH-AEJ4-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AEJ4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 76.0 years (27,742 days).
Specimen ALCH-AEJ4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51b6abb5-ca6a-4512-9d37-f298cb1084a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEJ4-NB1-A (Blood Derived Normal), aliquot ALCH-AEJ4-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0e7aebe-8284-453c-b9ae-bcbbc0fb655e

The open-access MAF lists 272 somatic variants for this specimen: 177 protein-altering or splice-affecting, 60 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 148, Silent 60, Intron 19, Nonsense Mutation 13, Frame Shift Del 7, RNA 7, 3'UTR 5, Splice Site 4, In Frame Del 2, Splice Region 2, 5'Flank 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 158/486 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.1335C>A p.I445= | Splice Region (SNP) | VAF 181/485 reads (37%) | catalogued as COSV56846959; called by muse, mutect2, varscan2
- ADAMTS8 | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs1177173965; called by muse, mutect2, varscan2
- ADAMTS9 | c.5087G>C p.G1696A | Missense Mutation (SNP) | VAF 59/104 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55780821; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2959G>A p.G987S | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1318870424, COSV65888187; called by muse, mutect2, varscan2
- AGO2 | c.1603G>A p.V535M | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs767897587; called by muse, mutect2, varscan2
- ANKS6 | c.2294G>C p.G765A | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1040340745; called by muse, mutect2
- ANO1 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 120/310 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs371196052; called by muse, mutect2, varscan2
- ANO3 | c.2324C>A p.A775D | Missense Mutation (SNP) | VAF 86/212 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56782985; called by muse, mutect2, varscan2
- AP3B1 | c.1658T>C p.L553S | Missense Mutation (SNP) | VAF 90/234 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs776017358; called by muse, mutect2, varscan2
- BDKRB2 | c.850C>A p.L284M | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV60015554; called by muse, mutect2, varscan2
- BICC1 | c.2918G>T p.R973L | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs188926102; called by muse, mutect2, varscan2
- CACNA2D1 | c.2375T>C p.I792T (on ENST00000356253 / NM_001366867.1; = p.I780T on NM_000722.4) | Missense Mutation (SNP) | VAF 115/312 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV62372898; called by muse, mutect2
- CDHR5 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 80/221 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.017); catalogued as rs368366044, COSV100363316; called by muse, mutect2, varscan2
- CHUK | c.449_450del p.I150Sfs*12 | Frame Shift Del (DEL) | VAF 71/252 reads (28%) | catalogued as rs1250696277; called by mutect2, pindel, varscan2
- CLCNKA | c.1156C>A p.H386N | Missense Mutation (SNP) | VAF 140/222 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1424613018; called by muse, mutect2, varscan2
- COL22A1 | c.3754G>T p.G1252C | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57332308, COSV57339371; called by muse, mutect2, varscan2
- CPZ | c.1862C>T p.A621V (on ENST00000360986 / NM_001014447.3; = p.A610V on NM_003652.3) | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs201930593, COSV100249106; called by muse, mutect2, varscan2
- CYFIP1 | c.3686G>A p.G1229D | Missense Mutation (SNP) | VAF 85/445 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.056); catalogued as rs1286140119; called by muse, mutect2, varscan2
- CYFIP1 | c.1099A>G p.S367G | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs746635990; called by muse, mutect2, varscan2
- CYLD | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs749160760, COSV61094920; called by muse, varscan2
- CYP11B1 | c.1343G>C p.R448P | Missense Mutation (SNP) | VAF 396/680 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM910103; called by muse, mutect2, varscan2
- DAPK1 | c.3083C>T p.T1028I | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as rs768041728; called by muse, mutect2, varscan2
- DCAF8L1 | c.1012T>C p.Y338H | Missense Mutation (SNP) | VAF 86/117 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101491440; called by muse, mutect2, varscan2
- DCLK3 | c.1870C>T p.R624* | Nonsense Mutation (SNP) | VAF 55/102 reads (54%) | catalogued as rs745309900, COSV69363405; called by muse, mutect2, varscan2
- DDC | c.560C>A p.S187* | Nonsense Mutation (SNP) | VAF 146/255 reads (57%) | catalogued as COSV63563651; called by muse, mutect2, varscan2
- DNHD1 | c.4696C>T p.R1566C | Missense Mutation (SNP) | VAF 84/244 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs545721460; called by muse, mutect2, varscan2
- DNM2 | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 75/211 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58957231; called by muse, mutect2, varscan2
- EVC2 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100186339; called by muse, mutect2, varscan2
- FNDC8 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.204); catalogued as rs139338261; called by muse, mutect2, varscan2
- GABPB2 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 109/154 reads (71%) | catalogued as rs768860075, COSV64460664; called by muse, mutect2, varscan2
- GPS2 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 34/67 reads (51%) | catalogued as COSV59747879; called by muse, mutect2, varscan2
- GTSE1 | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 24/297 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV101123857; called by muse, mutect2
- H1-10 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as rs765023771, COSV100412921, COSV100412961; called by muse, mutect2, varscan2
- HHATL | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs1559624292; called by muse, mutect2, varscan2
- IGLV1-40 | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 72/740 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as rs375256874; called by muse, mutect2, varscan2
- KCNV1 | c.1154G>T p.W385L | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV52087130; called by muse, mutect2, varscan2
- KDR | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 125/416 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.438); catalogued as rs760248367, COSV99818936; called by muse, mutect2, varscan2
- KEAP1 | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99407172; called by muse, varscan2
- KIF25 | c.701C>A p.A234E | Missense Mutation (SNP) | VAF 103/288 reads (36%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.996); catalogued as rs373765821; called by muse, mutect2, varscan2
- LRRTM3 | c.436C>A p.H146N | Missense Mutation (SNP) | VAF 95/290 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1436744091; called by muse, mutect2, varscan2
- NAGK | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as rs1172401721; called by muse, mutect2, varscan2
- NF1 | c.5018A>T p.N1673I (on ENST00000358273 / NM_001042492.3; = p.N1652I on NM_000267.3) | Missense Mutation (SNP) | VAF 133/310 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55985972; called by muse, mutect2, varscan2
- OR10H3 | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 155/390 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.159); catalogued as COSV59944052; called by muse, mutect2, varscan2
- PANK4 | c.1639G>T p.A547S | Missense Mutation (SNP) | VAF 72/122 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs372681543; called by muse, mutect2, varscan2
- PDZD2 | c.2389A>G p.I797V | Missense Mutation (SNP) | VAF 79/256 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99224253; called by muse, mutect2, varscan2
- PEG3 | c.1319C>T p.T440I | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV55645061; called by muse, mutect2, varscan2
- PI3 | c.293G>T p.C98F | Missense Mutation (SNP) | VAF 92/184 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1425391224; called by muse, mutect2, varscan2
- PKLR | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 162/207 reads (78%) | SIFT tolerated (0.2); PolyPhen benign (0.367); catalogued as rs773981429; called by muse, mutect2, varscan2
- PLCB4 | c.2044C>T p.R682W | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1485973570, COSV53810146; called by muse, mutect2
- PRAMEF17 | c.265C>A p.L89M | Missense Mutation (SNP) | VAF 72/123 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1204416672; called by muse, mutect2, varscan2
- PRDM14 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1351621312, COSV52570622, COSV52572032; called by muse, mutect2, varscan2
- R3HDM2 | c.2318C>T p.S773F | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1470705661, COSV61295867; called by muse, mutect2, varscan2
- RASAL1 | c.1472C>A p.A491E | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55656135; called by muse, mutect2, varscan2
- RBM14 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 159/548 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs764529837, COSV59558058; called by muse, mutect2, varscan2
- RPN2 | c.1222G>T p.A408S | Missense Mutation (SNP) | VAF 177/472 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs575988788; called by muse, mutect2, varscan2
- RRAS2 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56329798, COSV56330700, COSV56332575; called by muse, mutect2, varscan2
- SCOC | c.41G>T p.S14I | Missense Mutation (SNP) | VAF 133/407 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV100639545; called by muse, mutect2, varscan2
- SFMBT2 | c.2263G>T p.A755S | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62805580; called by muse, mutect2, varscan2
- SLIT1 | c.1409G>T p.R470L | Missense Mutation (SNP) | VAF 137/387 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs146769526; called by muse, mutect2, varscan2
- SNX20 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.579); catalogued as rs761260114; called by muse, mutect2, varscan2
- SPPL2C | c.324G>C p.W108C | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1377296603; called by muse, mutect2, varscan2
- STXBP5L | c.1401-2A>G p.X467_splice | Splice Site (SNP) | VAF 34/129 reads (26%) | catalogued as rs1422245922; called by muse, mutect2, varscan2
- SYBU | c.526C>G p.R176G (on ENST00000276646 / NM_001099754.2; = p.R175G on NM_017786.6) | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52618293; called by muse, mutect2, varscan2
- TAAR5 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs747432608, COSV57798497; called by muse, mutect2, varscan2
- TANC2 | c.2869C>T p.H957Y | Missense Mutation (SNP) | VAF 111/281 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs750182978; called by muse, mutect2, varscan2
- TMEM87A | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1007043015, COSV101100466; called by muse, mutect2, varscan2
- TP53 | c.472del p.R158Afs*12 | Frame Shift Del (DEL) | VAF 112/241 reads (46%) | catalogued as CM004341, CM121763, COSV52677865, COSV52699654, COSV52778687; called by mutect2, pindel, varscan2
- TRIM24 | c.3137G>A p.R1046H (on ENST00000343526 / NM_015905.3; = p.R1012H on NM_003852.4) | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as rs560006714, COSV58974214; called by muse, mutect2, varscan2
- TTN | c.38675A>C p.D12892A (on ENST00000591111; = p.D5468A on NM_003319.4) | Missense Mutation (SNP) | VAF 36/80 reads (45%) | PolyPhen benign (0.23); catalogued as COSV59918146; called by muse, mutect2, varscan2
- TYR | c.1200G>C p.W400C | Missense Mutation (SNP) | VAF 92/319 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM085762; called by muse, mutect2, varscan2
- UGT2B11 | c.120G>C p.K40N | Missense Mutation (SNP) | VAF 103/321 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.114); catalogued as rs556013852; called by muse, mutect2, varscan2
- UNC13C | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 91/218 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); catalogued as COSV104391651; called by muse, mutect2, varscan2
- VENTX | c.283C>G p.R95G | Missense Mutation (SNP) | VAF 88/261 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58084164; called by muse, mutect2, varscan2
- ZC3H18 | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 103/291 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1218820465, COSV56322450; called by muse, mutect2, varscan2
- ZFHX4 | c.8726C>T p.S2909F | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50641431; called by muse, mutect2, varscan2
- ZNF20 | c.1084_1085del p.T362* | Frame Shift Del (DEL) | VAF 49/187 reads (26%) | catalogued as rs754395783; called by pindel, varscan2
- ZNF699 | c.1601A>G p.K534R | Missense Mutation (SNP) | VAF 95/242 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV100426951; called by muse, mutect2, varscan2
- ZNF804B | c.897C>G p.N299K | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs989331135; called by muse, mutect2, varscan2
- ABCA9 | c.4500A>T p.R1500S | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ABCG8 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 323/834 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- ALG2 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AMER3 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- AMY2B | c.1252G>T p.G418C | Missense Mutation (SNP) | VAF 84/223 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- AP3B1 | c.2636G>T p.G879V | Missense Mutation (SNP) | VAF 180/578 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ARCN1 | c.1361T>A p.L454Q | Missense Mutation (SNP) | VAF 135/436 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ARHGAP35 | c.3904+1G>C p.X1302_splice | Splice Site (SNP) | VAF 134/346 reads (39%) | called by muse, mutect2, varscan2
- ARMC2 | c.124A>T p.T42S | Missense Mutation (SNP) | VAF 110/354 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- ASNSD1 | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ATP10B | c.3650A>G p.Y1217C | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1E | c.6162C>A p.Y2054* (on ENST00000367573 / NM_001205293.3; = p.Y2011* on NM_000721.4) | Nonsense Mutation (SNP) | VAF 81/121 reads (67%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.2377A>T p.M793L (on ENST00000356253 / NM_001366867.1; = p.M781L on NM_000722.4) | Missense Mutation (SNP) | VAF 117/308 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- CATSPERE | c.2485C>T p.P829S | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC7 | c.2306T>C p.V769A | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CCR6 | c.1066A>C p.I356L | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDCP1 | c.880G>A p.V294M | Missense Mutation (SNP) | VAF 81/147 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CENPE | c.1555A>T p.T519S | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP74 | c.909A>C p.Q303H | Missense Mutation (SNP) | VAF 107/158 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CLCN3 | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- CLPB | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- COL11A1 | c.2206G>T p.G736W | Missense Mutation (SNP) | VAF 118/206 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL24A1 | c.3329G>T p.G1110V | Missense Mutation (SNP) | VAF 68/126 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- COL9A3 | c.1439A>T p.Q480L | Missense Mutation (SNP) | VAF 120/247 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- CPS1 | c.3155G>C p.C1052S | Missense Mutation (SNP) | VAF 124/219 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CSDE1 | c.1124A>G p.H375R (on ENST00000358528 / NM_001007553.3; = p.H344R on NM_007158.6) | Missense Mutation (SNP) | VAF 104/154 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.276); called by muse, varscan2
- CSMD3 | c.3391C>A p.Q1131K (on ENST00000297405 / NM_001363185.1; = p.Q1027K on NM_052900.3) | Missense Mutation (SNP) | VAF 144/472 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- CSMD3 | c.2431T>C p.F811L (on ENST00000297405 / NM_001363185.1; = p.F707L on NM_052900.3) | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EDAR | c.118A>T p.T40S | Missense Mutation (SNP) | VAF 89/374 reads (24%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- GDPD2 | c.768G>C p.E256D | Missense Mutation (SNP) | VAF 92/135 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GHR | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 114/302 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- GLYR1 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- GOLGA8T | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 44/341 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- HDAC6 | c.2390C>G p.S797C | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- IGHG3 | c.1283T>A p.V428E | Missense Mutation (SNP) | VAF 777/944 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- IRAG1 | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 193/552 reads (35%) | called by muse, mutect2, varscan2
- KCNG2 | c.747_748del p.P250Tfs*5 | Frame Shift Del (DEL) | VAF 55/212 reads (26%) | called by pindel, varscan2
- KDM2A | c.508G>C p.D170H | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- KDM2A | c.3143G>T p.G1048V | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KPNB1 | c.1522C>G p.Q508E | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAGE3 | c.199G>T p.V67L | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, varscan2
- LRRC74A | c.486C>A p.Y162* | Nonsense Mutation (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- MASP1 | c.1247C>G p.A416G | Missense Mutation (SNP) | VAF 118/513 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- MICAL3 | c.1619T>C p.V540A | Missense Mutation (SNP) | VAF 80/257 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- MROH2B | c.2569C>A p.H857N | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- MROH7 | c.3231G>A p.M1077I | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MSH6 | c.1960_1962del p.M654del | In Frame Del (DEL) | VAF 89/285 reads (31%) | called by mutect2, pindel, varscan2
- MUC16 | c.6419T>C p.I2140T | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- MUC2 | c.2696del p.V899Afs*3 | Frame Shift Del (DEL) | VAF 121/404 reads (30%) | called by mutect2, pindel, varscan2
- MUC4 | c.14944A>T p.N4982Y (on ENST00000463781 / NM_018406.7; = p.N746Y on NM_004532.6) | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- NME8 | c.1388G>A p.S463N | Missense Mutation (SNP) | VAF 93/155 reads (60%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOM1 | c.1225G>T p.V409F | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, varscan2
- NUP62 | c.1301A>G p.Y434C | Missense Mutation (SNP) | VAF 369/894 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR1G1 | c.616A>C p.T206P | Missense Mutation (SNP) | VAF 73/252 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- OR4C11 | c.866A>T p.N289I | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- OR4F6 | c.389T>C p.L130P | Missense Mutation (SNP) | VAF 81/205 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR51S1 | c.646T>G p.L216V | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- OR5T2 | c.814G>T p.G272W | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OVCH1 | c.2956C>T p.L986F | Missense Mutation (SNP) | VAF 61/103 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- PALLD | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 162/430 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- PCDH15 | c.2042C>T p.T681I | Missense Mutation (SNP) | VAF 227/593 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- PCDHA11 | c.1160C>A p.S387* | Nonsense Mutation (SNP) | VAF 195/526 reads (37%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PHOSPHO1 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PPP1R3A | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 147/481 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRICKLE2 | c.1196A>G p.N399S (on ENST00000295902; = p.N343S on NM_198859.4) | Missense Mutation (SNP) | VAF 186/307 reads (61%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RARS2 | c.452-1G>T p.X151_splice | Splice Site (SNP) | VAF 54/188 reads (29%) | called by muse, mutect2, varscan2
- RHBDF2 | c.2141A>T p.Y714F | Missense Mutation (SNP) | VAF 165/476 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- RPS6KA1 | c.1883G>T p.R628L | Missense Mutation (SNP) | VAF 107/193 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RTL1 | c.1185G>A p.W395* | Nonsense Mutation (SNP) | VAF 146/182 reads (80%) | called by muse, mutect2, varscan2
- SCART1 | c.2185C>A p.Q729K | Missense Mutation (SNP) | VAF 44/423 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA6D | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SNAP91 | c.2199del p.Q734Sfs*31 | Frame Shift Del (DEL) | VAF 34/150 reads (23%) | called by pindel, varscan2
- SPAG17 | c.5227T>C p.C1743R | Missense Mutation (SNP) | VAF 58/94 reads (62%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPANXB1 | c.259C>G p.Q87E | Missense Mutation (SNP) | VAF 175/1046 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- SPG21 | c.-24G>T | Splice Region (SNP) | VAF 21/87 reads (24%) | called by muse, mutect2, varscan2
- SRGAP2C | c.1247G>T p.S416I | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- SRGAP3 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 45/83 reads (54%) | called by muse, mutect2, varscan2
- SYNE1 | c.13397C>T p.T4466I (on ENST00000367255 / NM_182961.4; = p.T4395I on NM_033071.3) | Missense Mutation (SNP) | VAF 29/291 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBC1D30 | c.644-1G>T p.X215_splice (on ENST00000542120; = p.X52_splice on NM_015279.2 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 70/140 reads (50%) | called by muse, mutect2, varscan2
- TERB1 | c.895A>T p.K299* | Nonsense Mutation (SNP) | VAF 67/155 reads (43%) | called by muse, mutect2, varscan2
- TMC1 | c.2269G>T p.A757S | Missense Mutation (SNP) | VAF 101/446 reads (23%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.007); called by muse, varscan2
- TMEM145 | c.1084G>T p.V362F | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- TREX1 | c.595_612del p.G199_L204del (on ENST00000625293 / NM_033629.6; = p.G189_L194del on NM_007248.5) | In Frame Del (DEL) | VAF 126/265 reads (48%) | called by mutect2, pindel, varscan2
- TTN | c.58906G>T p.D19636Y (on ENST00000591111; = p.D12212Y on NM_003319.4) | Missense Mutation (SNP) | VAF 26/218 reads (12%) | PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TUBE1 | c.529A>G p.I177V | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE2NL | c.406C>A p.Q136K | Missense Mutation (SNP) | VAF 90/128 reads (70%) | SIFT tolerated (0.53); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- USP10 | c.1690G>A p.V564I | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- USP32 | c.281del p.E94Gfs*48 | Frame Shift Del (DEL) | VAF 42/116 reads (36%) | called by mutect2, pindel, varscan2
- VPS13C | c.4891A>T p.I1631F (on ENST00000644861 / NM_020821.3; = p.I1588F on NM_017684.5) | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- YIPF7 | c.655G>T p.G219C | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.05); called by muse, mutect2
- ZFYVE16 | c.4261G>T p.E1421* | Nonsense Mutation (SNP) | VAF 52/154 reads (34%) | called by muse, varscan2
- ZNF208 | c.3169T>A p.Y1057N | Missense Mutation (SNP) | VAF 85/273 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- ZNF235 | c.1972G>T p.E658* | Nonsense Mutation (SNP) | VAF 54/143 reads (38%) | called by muse, mutect2, varscan2
- ZNF516 | c.2891C>T p.P964L | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF541 | c.2080C>G p.P694A | Missense Mutation (SNP) | VAF 79/198 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF675 | c.913dup p.I305Nfs*11 | Frame Shift Ins (INS) | VAF 65/171 reads (38%) | called by mutect2, varscan2
- ZNF717 | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- AC136428.1 | c.99T>G p.P33= | Silent (SNP) | VAF 48/136 reads (35%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.2721C>A p.T907= | Silent (SNP) | VAF 78/232 reads (34%) | called by mutect2, varscan2
- ADGRB3 | c.972A>T p.T324= | Silent (SNP) | VAF 85/209 reads (41%) | called by muse, mutect2, varscan2
- ADRA1D | c.954G>T p.A318= | Silent (SNP) | VAF 88/203 reads (43%) | catalogued as COSV101062907; called by muse, mutect2, varscan2
- ANKFN1 | c.1917C>T p.H639= | Silent (SNP) | VAF 61/150 reads (41%) | catalogued as rs773759113, COSV59449286; called by muse, mutect2, varscan2
- AP3D1 | c.3309C>T p.C1103= | Silent (SNP) | VAF 52/166 reads (31%) | catalogued as rs375487362; called by muse, mutect2, varscan2
- APBB1 | c.1326G>T p.L442= | Silent (SNP) | VAF 70/217 reads (32%) | called by muse, mutect2, varscan2
- ARHGAP15 | c.1260C>A p.A420= | Silent (SNP) | VAF 61/85 reads (72%) | called by muse, mutect2, varscan2
- ARHGAP6 | c.327G>A p.P109= | Silent (SNP) | VAF 147/215 reads (68%) | catalogued as rs142502410; called by muse, mutect2, varscan2
- B3GNT9 | c.1095C>T p.H365= | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as COSV54627963; called by muse, mutect2, varscan2
- B4GALNT4 | c.2187G>A p.L729= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs766461005; called by muse, varscan2
- BSX | c.154C>T p.L52= | Silent (SNP) | VAF 71/198 reads (36%) | catalogued as COSV58005329; called by muse, mutect2, varscan2
- CCDC168 | c.11028C>T p.S3676= | Silent (SNP) | VAF 52/73 reads (71%) | called by muse, mutect2, varscan2
- CHD9 | c.5589A>G p.Q1863= | Silent (SNP) | VAF 136/424 reads (32%) | called by muse, mutect2, varscan2
- CNTN2 | c.159G>A p.T53= | Silent (SNP) | VAF 243/340 reads (71%) | catalogued as rs907497961; called by muse, mutect2, varscan2
- CSMD3 | c.7374C>T p.A2458= (on ENST00000297405 / NM_001363185.1; = p.A2354= on NM_052900.3) | Silent (SNP) | VAF 254/482 reads (53%) | called by muse, varscan2
- CTDSPL2 | c.855A>C p.T285= | Silent (SNP) | VAF 23/123 reads (19%) | called by muse, mutect2, varscan2
- CYP11B2 | c.225G>T p.L75= | Silent (SNP) | VAF 458/747 reads (61%) | called by muse, mutect2, varscan2
- CYP4F8 | c.285C>A p.I95= | Silent (SNP) | VAF 116/313 reads (37%) | catalogued as COSV57853084; called by muse, mutect2, varscan2
- DCAF12L1 | c.651G>T p.V217= | Silent (SNP) | VAF 107/144 reads (74%) | called by muse, mutect2, varscan2
- EBI3 | c.570C>T p.L190= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs768210906; called by muse, mutect2, varscan2
- F2 | c.1623G>T p.R541= | Silent (SNP) | VAF 46/123 reads (37%) | called by muse, mutect2, varscan2
- FASN | c.4836T>A p.R1612= | Silent (SNP) | VAF 209/586 reads (36%) | called by muse, mutect2, varscan2
- FAT1 | c.10905A>G p.T3635= | Silent (SNP) | VAF 111/240 reads (46%) | called by muse, mutect2, varscan2
- GABRG1 | c.924T>A p.T308= | Silent (SNP) | VAF 47/126 reads (37%) | called by muse, mutect2, varscan2
- GOLGA3 | c.430C>T p.L144= | Silent (SNP) | VAF 60/113 reads (53%) | called by muse, mutect2, varscan2
- GPR31 | c.181C>T p.L61= | Silent (SNP) | VAF 132/341 reads (39%) | called by muse, mutect2, varscan2
- LPCAT1 | c.1215G>T p.V405= | Silent (SNP) | VAF 63/199 reads (32%) | called by muse, mutect2, varscan2
- LRRC10 | c.441G>A p.K147= | Silent (SNP) | VAF 133/231 reads (58%) | called by muse, mutect2, varscan2
- MAP3K15 | c.1956T>C p.N652= | Silent (SNP) | VAF 90/126 reads (71%) | called by muse, mutect2, varscan2
- MET | c.4102C>T p.L1368= | Silent (SNP) | VAF 99/335 reads (30%) | called by muse, mutect2, varscan2
- MROH1 | c.4812G>A p.P1604= | Silent (SNP) | VAF 171/609 reads (28%) | catalogued as rs1188258803; called by muse, mutect2, varscan2
- MRPS9 | c.27C>G p.G9= | Silent (SNP) | VAF 180/328 reads (55%) | called by muse, mutect2, varscan2
- MTMR7 | c.987G>A p.E329= | Silent (SNP) | VAF 66/111 reads (59%) | called by muse, mutect2, varscan2
- NECTIN1 | c.720T>C p.T240= | Silent (SNP) | VAF 28/512 reads (5%) | called by muse, mutect2
- NPAP1 | c.279C>T p.A93= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs1204359223; called by muse, mutect2, varscan2
- OTUD6A | c.834C>T p.G278= | Silent (SNP) | VAF 30/35 reads (86%) | catalogued as rs374307268; called by muse, mutect2, varscan2
- PGS1 | c.78G>A p.G26= | Silent (SNP) | VAF 38/174 reads (22%) | called by muse, mutect2, varscan2
- PHOSPHO1 | c.480G>C p.L160= | Silent (SNP) | VAF 16/142 reads (11%) | called by muse, mutect2, varscan2
- PHRF1 | c.3264G>A p.T1088= (on ENST00000264555 / NM_001286581.2; = p.T1087= on NM_020901.4) | Silent (SNP) | VAF 106/267 reads (40%) | catalogued as rs748060075; called by muse, mutect2, varscan2
- PLA2G4C | c.465G>A p.L155= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs1013202597; called by muse, mutect2, varscan2
- PNPLA6 | c.330G>A p.K110= (on ENST00000414982 / NM_001166111.2; = p.K62= on NM_006702.5) | Silent (SNP) | VAF 175/506 reads (35%) | called by muse, mutect2, varscan2
- PSKH2 | c.6G>A p.G2= | Silent (SNP) | VAF 24/31 reads (77%) | catalogued as rs536501005; called by muse, mutect2, varscan2
- RELA | c.183C>T p.I61= | Silent (SNP) | VAF 34/90 reads (38%) | called by muse, mutect2, varscan2
- SLC16A9 | c.723G>A p.T241= | Silent (SNP) | VAF 129/392 reads (33%) | catalogued as COSV68100669; called by muse, mutect2, varscan2
- SLC18A3 | c.1023C>T p.G341= | Silent (SNP) | VAF 18/200 reads (9%) | catalogued as rs1199213347, COSV60327577; called by muse, mutect2
- SLCO2B1 | c.1233G>T p.L411= | Silent (SNP) | VAF 100/250 reads (40%) | called by muse, mutect2, varscan2
- SORCS1 | c.1419A>T p.A473= | Silent (SNP) | VAF 35/93 reads (38%) | called by muse, mutect2, varscan2
- SPG7 | c.1932G>A p.L644= (on ENST00000268704; = p.L651= on NM_003119.4) | Silent (SNP) | VAF 76/248 reads (31%) | catalogued as rs1057523048, COSV51950919; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPTA1 | c.4518C>T p.Y1506= | Silent (SNP) | VAF 318/426 reads (75%) | catalogued as rs754126349; called by muse, mutect2, varscan2
- STXBP1 | c.852C>T p.D284= | Silent (SNP) | VAF 86/738 reads (12%) | catalogued as rs141782684; ClinVar: likely benign; called by muse, mutect2, varscan2
- SUSD5 | c.1017C>T p.I339= | Silent (SNP) | VAF 102/174 reads (59%) | called by muse, mutect2, varscan2
- TTN | c.67080C>A p.A22360= (on ENST00000591111; = p.A14936= on NM_003319.4) | Silent (SNP) | VAF 46/79 reads (58%) | called by muse, mutect2, varscan2
- XXYLT1 | c.249C>A p.G83= | Silent (SNP) | VAF 46/165 reads (28%) | catalogued as COSV100117942; called by muse, mutect2, varscan2
- ZDHHC11 | c.693G>T p.L231= | Silent (SNP) | VAF 132/610 reads (22%) | catalogued as rs1374139913; called by muse, varscan2
- ZNF317 | c.699G>T p.T233= | Silent (SNP) | VAF 212/572 reads (37%) | catalogued as COSV56110690; called by muse, mutect2, varscan2
- ZNF628 | c.1029G>T p.P343= | Silent (SNP) | VAF 44/121 reads (36%) | called by muse, mutect2, varscan2
- ZNF727 | c.93T>C p.D31= | Silent (SNP) | VAF 61/179 reads (34%) | called by muse, mutect2, varscan2
- ZNF735 | c.192G>A p.L64= | Silent (SNP) | VAF 78/231 reads (34%) | catalogued as rs866970341; called by muse, mutect2, varscan2
- ZNF804B | c.3792A>T p.A1264= | Silent (SNP) | VAF 108/296 reads (36%) | called by muse, mutect2, varscan2
- ABL2 | c.158-9632T>C | Intron (SNP) | VAF 170/244 reads (70%) | catalogued as rs1326680522, COSV61019427; called by muse, mutect2, varscan2
- AHR | c.*31G>A | 3'UTR (SNP) | VAF 30/189 reads (16%) | called by muse, mutect2, varscan2
- AP000679.1 | n.562C>T | RNA (SNP) | VAF 135/415 reads (33%) | catalogued as rs762681008; called by muse, mutect2, varscan2
- ASCC3 | c.801+9G>C | Intron (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2
- ATP1A2 | c.118-56C>T | Intron (SNP) | VAF 220/289 reads (76%) | called by muse, mutect2, varscan2
- BAGE2 | n.277G>T | RNA (SNP) | VAF 36/482 reads (7%) | called by muse, mutect2
- BTBD7 | c.1608+33A>G | Intron (SNP) | VAF 27/101 reads (27%) | called by muse, varscan2
- COL1A2 | c.2782-11T>C | Intron (SNP) | VAF 137/384 reads (36%) | catalogued as rs373578055; called by muse, mutect2, varscan2
- DLG2 | c.1978+3745G>C | Intron (SNP) | VAF 26/188 reads (14%) | called by muse, mutect2, varscan2
- DNAH14 | c.9205+9252G>C | Intron (SNP) | VAF 96/293 reads (33%) | called by muse, mutect2, varscan2
- EPHB2 | c.2852+12G>T | Intron (SNP) | VAF 90/372 reads (24%) | called by muse, mutect2, varscan2
- FKBP1B | c.85+152C>A | Intron (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- GLTPP1 | n.362T>A | RNA (SNP) | VAF 72/156 reads (46%) | called by muse, mutect2, varscan2
- GP1BB | chr22:19723427 G>A | 5'Flank (SNP) | VAF 108/251 reads (43%) | catalogued as rs557317254; called by muse, mutect2, varscan2
- GSDMD | c.*39C>A | 3'UTR (SNP) | VAF 134/553 reads (24%) | catalogued as rs1286800867; called by muse, mutect2, varscan2
- HNRNPL | c.1711+15_1711+16del | Intron (DEL) | VAF 50/155 reads (32%) | called by pindel, varscan2
- HSD17B12 | c.283+766G>C | Intron (SNP) | VAF 26/92 reads (28%) | called by muse, mutect2, varscan2
- KCNMA1 | c.1224-45C>T | Intron (SNP) | VAF 39/98 reads (40%) | called by muse, mutect2, varscan2
- LEKR1 | c.*438A>G | 3'UTR (SNP) | VAF 44/170 reads (26%) | catalogued as rs768885162; called by muse, varscan2
- LILRB5 | c.1357+77C>A | Intron (SNP) | VAF 56/136 reads (41%) | called by muse, mutect2, varscan2
- MIR6859-4 | chr16:16991 C>G | 3'Flank (SNP) | VAF 80/848 reads (9%) | called by muse, mutect2, varscan2
- NCL | c.1448-203C>A | Intron (SNP) | VAF 90/178 reads (51%) | called by muse, mutect2, varscan2
- NOS1 | c.*41C>T | 3'UTR (SNP) | VAF 5/28 reads (18%) | catalogued as rs1345125240; called by muse, mutect2, varscan2
- OBSCN | c.18662-2039G>T | Intron (SNP) | VAF 121/156 reads (78%) | called by muse, mutect2, varscan2
- OR10V2P | n.322T>A | RNA (SNP) | VAF 132/334 reads (40%) | called by muse, mutect2, varscan2
- OSGIN1 | n.1665C>T | RNA (SNP) | VAF 140/417 reads (34%) | catalogued as rs148300856; called by muse, mutect2, varscan2
- PDE4DIP | c.637-7080C>T | Intron (SNP) | VAF 187/265 reads (71%) | catalogued as rs1399606653; called by muse, mutect2, varscan2
- RIMS3 | c.-17C>T | 5'UTR (SNP) | VAF 50/80 reads (63%) | called by muse, mutect2
- SCP2D1-AS1 | n.153G>C | RNA (SNP) | VAF 64/166 reads (39%) | called by muse, mutect2, varscan2
- SNORD115-29 | n.12G>T | RNA (SNP) | VAF 155/522 reads (30%) | called by muse, varscan2
- SNORD116-29 | chr15:25101546 G>C | 5'Flank (SNP) | VAF 105/240 reads (44%) | called by muse, mutect2, varscan2
- TTYH1 | c.126+1131C>A | Intron (SNP) | VAF 103/381 reads (27%) | catalogued as rs1486735499; called by muse, mutect2, varscan2
- UMPS | c.*3873C>T | 3'UTR (SNP) | VAF 23/132 reads (17%) | catalogued as rs993982649; called by muse, mutect2, varscan2
- ZEB1 | c.58+43959G>A | Intron (SNP) | VAF 89/302 reads (29%) | called by mutect2, varscan2
- ZNF141 | c.226+5813G>T | Intron (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
